TCGA case TCGA-BT-A20Q — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/419deaac-ea45-4bdd-9fa0-b5cd8429b44f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Dead; Days to death: 593 days (1.6 years).

Diagnoses (2)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.0; Tissue or organ of origin: Trigone of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 73.3 years (26,778 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC clinical T: T3b; AJCC pathologic T: T3b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 593 days (1.6 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 23.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Bone, NOS. Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (2 entries)
- Days to follow up: 593 days (1.6 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Timepoint: Post Initial Treatment.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.
- Occupation type: General Office Clerks.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BT-A20Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 320 mg.
  Slide TCGA-BT-A20Q-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BT-A20Q-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BT-A20Q-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 370 mg.
  Slide TCGA-BT-A20Q-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation primary: Clerical clerk; Occupation primary industry: Grocery store; Tobacco smoking history indicator: 1; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 593 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 593 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 593 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BT-A20Q-01A-11D-A14V-01): tumor purity 0.68, ploidy 2.02, whole-genome doublings 0.
